Somatic mutation profile of tumor specimen TCGA-XF-AAMT-01A (aliquot TCGA-XF-AAMT-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 75.0 years (27,397 days).
Specimen TCGA-XF-AAMT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccf5ccce-764d-4359-b98c-b014926d5356.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMT-10A (Blood Derived Normal), aliquot TCGA-XF-AAMT-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8fa907f-c7e5-412d-92f5-d061e3f719f8

The open-access MAF lists 117 somatic variants for this specimen: 91 protein-altering or splice-affecting, 25 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 25, Frame Shift Del 11, Splice Site 5, Nonsense Mutation 2, Nonstop Mutation 1, In Frame Del 1, Translation Start Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.3127G>T p.V1043F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs1334532322, COSV55790686, COSV55790849; called by muse, mutect2, varscan2
- ADGRG2 | c.2995C>A p.R999S (on ENST00000379869 / NM_001079858.3; = p.R996S on NM_005756.4) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV61341370; called by muse, mutect2, varscan2
- ADIPOR1 | c.1058A>T p.Y353F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV61852487; called by muse, mutect2, varscan2
- ADIPOR1 | c.1057T>A p.Y353N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV61852492; called by muse, mutect2, varscan2
- AKAP1 | c.1440C>G p.I480M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as COSV58473034; called by muse, mutect2, varscan2
- AMER1 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV57668990; called by muse, mutect2, varscan2
- ATG4D | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV57265890; called by muse, mutect2, varscan2
- ATP2B4 | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV58183926; called by muse, mutect2, varscan2
- C1S | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); catalogued as rs373197181; called by muse, mutect2, varscan2
- C2CD2 | c.1861A>C p.K621Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61600512; called by muse, mutect2, varscan2
- CACNB2 | c.1770C>A p.H590Q (on ENST00000324631 / NM_201596.3; = p.H535Q on NM_000724.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.993); catalogued as COSV56647176; called by muse, mutect2, varscan2
- CCDC66 | c.861_863del p.W288del (on ENST00000394672 / NM_001353147.1; = p.W254del on NM_001012506.5 and 6 other RefSeq transcripts) | In Frame Del (DEL) | VAF 27/74 reads (36%) | catalogued as COSV58309454; called by mutect2, pindel, varscan2
- CFAP20DC | c.818C>G p.S273C (on ENST00000482387 / NM_001351530.2; = p.S148C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55927584; called by muse, mutect2, varscan2
- CREBBP | c.3369+2T>A p.X1123_splice | Splice Site (SNP) | VAF 12/46 reads (26%) | catalogued as COSV52141100; called by muse, mutect2, varscan2
- DAGLB | c.467_474del p.D156Gfs*17 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | catalogued as COSV51706915; called by mutect2, pindel, varscan2
- DNAH1 | c.8353G>A p.V2785M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1276242008, COSV70236304; called by muse, mutect2, varscan2
- DOCK1 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54760205; called by muse, mutect2, varscan2
- ELMO1 | c.246T>G p.A82= | Splice Region (SNP) | VAF 20/55 reads (36%) | catalogued as COSV60325157, COSV60325807; called by muse, mutect2, varscan2
- EP400 | c.1785G>C p.K595N | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57786502; called by muse, mutect2, varscan2
- FNIP2 | c.1772A>T p.H591L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52445875; called by muse, mutect2, varscan2
- GPR50 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV54439942, COSV54442884; called by muse, mutect2, varscan2
- HTR3C | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.268); catalogued as COSV59177319; called by muse, mutect2, varscan2
- IFT140 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs139286030; called by muse, mutect2, varscan2
- KCNB2 | c.11A>T p.K4M | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV73053008; called by muse, mutect2, varscan2
- KCTD21 | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); catalogued as COSV60741791; called by muse, mutect2, varscan2
- KDM8 | c.780C>G p.S260R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV53731949; called by muse, mutect2, varscan2
- LAMA4 | c.1945G>A p.D649N (on ENST00000230538 / NM_001105206.3; = p.D642N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV57904955; called by muse, mutect2, varscan2
- LHX3 | c.233G>C p.C78S (on ENST00000371748 / NM_178138.6; = p.C83S on NM_014564.5) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1261178919, COSV65583456; called by muse, mutect2, varscan2
- LY86 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750844218, COSV57913974; called by muse, mutect2, varscan2
- MAGEA6 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV61449491; called by muse, mutect2, varscan2
- MAGEB18 | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57464612; called by muse, mutect2, varscan2
- MAMSTR | c.961G>A p.D321N (on ENST00000318083 / NM_001130915.2; = p.D218N on NM_182574.2) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs745349713, COSV58882078, COSV58883309; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MBTPS1 | c.2803C>G p.P935A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1260304879, COSV58572606; called by muse, mutect2, varscan2
- MKI67 | c.1656+1G>A p.X552_splice | Splice Site (SNP) | VAF 46/167 reads (28%) | catalogued as rs751293626, COSV64076982, COSV64078030; called by muse, mutect2, varscan2
- MMD2 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV68661583; called by muse, mutect2, varscan2
- MORC1 | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV51724308, COSV51731302; called by muse, mutect2, varscan2
- MYH1 | c.3220G>C p.E1074Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV56845761, COSV56857133; called by muse, mutect2, varscan2
- NCKAP5 | c.1619G>A p.C540Y | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.268); catalogued as COSV58475246; called by muse, mutect2, varscan2
- NKG7 | c.431_439+2del p.X144_splice | Splice Site (DEL) | VAF 11/97 reads (11%) | catalogued as COSV52468195; called by mutect2, pindel
- NKTR | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51775369; called by muse, mutect2, varscan2
- NLRC5 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.241); catalogued as COSV52663144; called by muse, mutect2, varscan2
- OPHN1 | c.179T>G p.F60C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62786928; called by muse, mutect2, varscan2
- OPN1LW | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 62/444 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV64049301, COSV64049516; called by muse, mutect2, varscan2
- OR2J2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV65848403; called by muse, mutect2, varscan2
- PDE1A | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.119); catalogued as COSV59536696; called by muse, mutect2, varscan2
- PLB1 | c.3377C>G p.S1126C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100579885, COSV59835680; called by muse, mutect2, varscan2
- PRKCSH | c.1438A>C p.T480P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as COSV52954137; called by muse, mutect2, varscan2
- PTPRD | c.4160C>T p.A1387V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61974328; called by muse, mutect2, varscan2
- PXDNL | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1222145180, COSV62498554; called by muse, mutect2, varscan2
- RBL1 | c.1849C>G p.L617V | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV60333799; called by muse, mutect2, varscan2
- REXO4 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64242306; called by muse, mutect2, varscan2
- ROS1 | c.4666G>A p.G1556R | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362301601, COSV63861674; called by muse, mutect2, varscan2
- SEMA4D | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV59400944; called by muse, mutect2, varscan2
- SEPTIN4 | c.538+1G>A p.X180_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as COSV57899586; called by muse, mutect2, varscan2
- SHROOM3 | c.2026A>C p.S676R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99935469; called by muse, mutect2
- SLC26A7 | c.1481T>C p.M494T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV52604663; called by muse, mutect2, varscan2
- SOSTDC1 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV61049945; called by muse, mutect2, varscan2
- SOX1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100447135; called by muse, mutect2, varscan2
- SPACA1 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52761501; called by muse, mutect2
- TENM4 | c.6715T>A p.Y2239N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745513028, COSV53671224; called by muse, mutect2, varscan2
- TEX13B | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as COSV57203859; called by muse, mutect2, varscan2
- THSD7A | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV70260711; called by muse, mutect2, varscan2
- TPTE2 | c.1431C>A p.F477L (on ENST00000400230 / NM_199254.2; = p.F400L on NM_130785.3) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV55019526, COSV99691054; called by muse, mutect2
- TRERF1 | c.2479G>C p.E827Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV61678106; called by muse, mutect2, varscan2
- TRERF1 | c.2357G>A p.R786K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV61678145; called by muse, varscan2
- TRMT5 | c.1270G>C p.D424H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV54204946; called by muse, varscan2
- TRMT5 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as COSV54204954; called by muse, varscan2
- TRPM3 | c.3568G>A p.D1190N (on ENST00000357533 / NM_001366142.2; = p.D1045N on NM_020952.6) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV62595075; called by muse, mutect2, varscan2
- TRPM3 | c.2401C>G p.P801A (on ENST00000357533 / NM_001366142.2; = p.P644A on NM_020952.6) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62595087; called by muse, mutect2
- ZFYVE27 | c.861T>A p.F287L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV61747381; called by muse, mutect2, varscan2
- ZNF175 | c.1583A>G p.E528G | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1329252402, COSV51798472; called by muse, mutect2, varscan2
- ZNF225 | c.1845G>C p.Q615H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV53473213; called by muse, mutect2, varscan2
- ZNF622 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as COSV58073806, COSV58075195; called by muse, mutect2, varscan2
- ZP2 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99076911, COSV99559856; called by muse, mutect2, varscan2
- ENPP3 | c.74_78+6del p.X25_splice | Splice Site (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- EPHA5 | c.2564_2582del p.F855Sfs*6 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- GNL3L | c.1467_1471del p.C490Qfs*11 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- GPR179 | c.5912C>A p.S1971Y (on ENST00000621958; = p.S1970Y on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IGKV2-30 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by mutect2, varscan2
- KMT2C | c.8427del p.K2809Nfs*14 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel*, varscan2
- KMT2D | c.10986_10990del p.M3662Ifs*11 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- LRIF1 | c.1838_1839del p.E613Vfs*14 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by pindel, varscan2
- PTPRU | c.2383_2389del p.Y795Rfs*6 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- RRP9 | c.1428_*10del | Nonstop Mutation (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- SLC1A6 | c.1611del p.S538Afs*? | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- SRMS | c.108del p.N37Tfs*34 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel*, varscan2*
- XIRP2 | c.2627_2634del p.N876Ifs*7 (on ENST00000628543; = p.N1051Ifs*7 on NM_152381.6) | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- ZNF658 | c.1970C>A p.P657H | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF831 | c.631_635del p.G211Pfs*88 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- ACACB | c.4206C>T p.A1402= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV58146617; called by muse, mutect2, varscan2
- AKAP1 | c.1327C>T p.L443= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV58473018; called by muse, mutect2, varscan2
- ARRDC2 | c.51C>T p.T17= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1191733078, COSV99716974; called by muse, mutect2, varscan2
- B4GALNT1 | c.780G>T p.R260= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs747840275, COSV57544298; called by muse, mutect2, varscan2
- BTBD6 | c.630C>T p.V210= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV59273642; called by muse, mutect2, varscan2
- CDH23 | c.576G>A p.E192= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV54952874; called by muse, mutect2, varscan2
- CEP192 | c.5946T>A p.T1982= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV58070705; called by muse, mutect2, varscan2
- COL4A4 | c.2241C>T p.P747= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs374510402; called by muse, mutect2, varscan2
- CTTNBP2 | c.3516A>T p.L1172= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV50475996; called by muse, mutect2, varscan2
- DENND10 | c.396G>A p.K132= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV63858252; called by muse, mutect2, varscan2
- DUSP6 | c.777C>T p.P259= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs1330121964, COSV54379537; called by muse, mutect2, varscan2
- ERAP2 | c.2166C>A p.L722= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV101163782, COSV65940210; called by muse, mutect2, varscan2
- FBXW9 | c.408C>T p.C136= (on ENST00000587955; = p.C146= on NM_032301.3) | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs762766485, COSV63510189; called by muse, mutect2, varscan2
- GALNTL5 | c.132A>C p.S44= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV67181186; called by muse, mutect2, varscan2
- GATA3 | c.702C>T p.F234= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs199565632, COSV60522496; called by muse, mutect2, varscan2
- GPR45 | c.615C>T p.F205= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs267598822, COSV99306969, COSV99307232; called by muse, mutect2
- MBTPS1 | c.2802G>A p.K934= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs962171821, COSV58572611; called by muse, mutect2, varscan2
- METTL7B | c.654C>T p.S218= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1274408928, COSV57697464; called by muse, mutect2, varscan2
- NR1H2 | c.252C>T p.H84= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs763195837, COSV53800323; called by muse, mutect2, varscan2
- OR7D2 | c.345G>C p.L115= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as COSV60141335; called by muse, mutect2, varscan2
- STPG1 | c.666G>T p.T222= (on ENST00000337248 / NM_001199013.2; = p.T175= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV50225457; called by muse, mutect2, varscan2
- SYNE1 | c.1275G>C p.L425= (on ENST00000367255 / NM_182961.4; = p.L432= on NM_033071.3) | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV55103193, COSV99573468; called by muse, mutect2, varscan2
- TAS2R41 | c.390G>T p.V130= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV68764910, COSV68765884; called by muse, mutect2
- TMEM127 | c.210C>T p.D70= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs1553437721, COSV99302762; ClinVar: likely benign; called by muse, mutect2
- ZBTB24 | c.144C>T p.F48= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV57783381; called by muse, mutect2
- MTRNR2L6 | chr7:142671037 T>C | 3'Flank (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
